Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2T, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2T-01A (Primary Tumor).

Female

Surgery Date:

DIAGNOSIS:

Liver, right segments IV-VIII, trisegmentectomy: Grade 3 (of 4) cholangiocarcinoma, forming an dominant mass (11.5 x 9.2 x 8.6 cm) and multiple (15) other separate nodules (ranging in size from 0.3 x 0.3 x 0.3 cm to 4.2 x 3.6 x 3.5 cm) within the liver parenchyma. The tumors are not encapsulated. Focal angiolymphatic invasion is noted. The surgical margins are negative for tumor.

Liver, left lobe (No.1 to No.3), biopsy: Benign hepatic parenchyma with mild steatosis, all specimens.

Soft tissue, caudate region, biopsy: A single (1) lymph node is negative for tumor.

Peritoneum, biopsy: Benign hepatic parenchyma.

Gallbladder, cholecystectomy: Chronic cholecystitis. A single (1) regional lymph node is negative for tumor.

Lymph nodes, hepatic artery, excision: A single (1) hepatic artery lymph node is negative for tumor.

Immunoperoxidase studies performed on paraffin sections of the liver right segments IV-VIII reveal the neoplastic cells are positive for cytokeratin 7 and negative for cytokeratin 20, CDX2, thyroid transcription factor-1 (TTF-1), and estrogen receptor protein. These findings are consistent with the above diagnosis.

ICD -0-3
Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct C22.1
JW 3/8/14

Source: NCI Genomic Data Commons file 4035f0c7-cd79-42f1-bd51-f4602dbdb7f3 (TCGA-W5-AA2T.16492F27-A257-4DC8-84E8-E1F14B7DC3FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).